Gene-level copy-number profile of tumor specimen TCGA-50-6673-01A from TCGA case TCGA-50-6673, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage I; Age at diagnosis: 84.0 years (30,689 days).
Specimen TCGA-50-6673-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.47a630db-cf49-46cf-a41a-4ab09a5af4b0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-50-6673-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 825 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c343a4d1-d361-453a-a820-185bebad4b62

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 5,571; copy number 3: 15,709; copy number 4: 29,714; copy number 5: 3,364; copy number 6: 2,761; copy number 7: 872; copy number 8: 267; copy number 9: 175; copy number 10: 32; copy number 11: 896; copy number 12: 295; copy number 13: 17; copy number 14: 8; copy number 15: 16; copy number 16: 40; copy number 17: 30; copy number 18: 16; copy number 40: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-50-6673-01A-11D-1943-01): tumor purity 0.35, ploidy 3.74, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,540 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:104,125,268–105,636,637, 36 genes, copy number 9–11 (within-gene range 3–11): AC096554.1, AHCYP3, AC068535.1, LINC01831, AC068535.2, LINC01102, LINC01103, AC013402.2, AC013402.3, AC068057.3, AC013402.1, RPL23AP27, AC068057.1, AC068057.2, SNORA72, LINC01114, HMGB3P11, PANTR1, AC018730.1, POU3F3, LINC01159, AC010884.1, MRPS9-AS2, MRPS9, MRPS9-AS1, LINC01918, GPR45, AC012360.2, TGFBRAP1, AC012360.1, AC012360.3, C2orf49, FHL2, AC108058.1, AC018802.1, AC018802.2.
- chr2:176,989,418–178,142,651, 34 genes, copy number 12: AC074286.1, AC079305.2, RNA5SP112, STUB1P1, Y_RNA, KRT8P40, HNRNPA3, MIR4444-1, NFE2L2, DNAJC19P5, MIR3128, AC079305.1, AC019080.1, AC019080.3, AC019080.4, MIR6512, AC019080.5, H3P7, AC019080.2, AGPS, TTC30B, AC073834.1, TTC30A, PDE11A, PDE11A, PDE11A-AS1, AC011998.2, API5P2, SDHDP5, RNU6-629P, CYCTP, AC011998.1, RBM45, RNU5E-9P.
- chr6:48,213,604–48,214,794, 1 gene, copy number 11: RBMXP1.
- chr6:112,236,093–114,545,335, 35 genes, copy number 9: LAMA4-AS1, AL365214.2, AL365214.1, RFPL4B, RPSAP45, KRT18P65, FEM1AP3, AL365214.3, AL357514.1, PA2G4P5, AL360085.1, RNU6-1163P, AL360015.1, FCF1P10, AL049695.1, SOCS5P5, AL589684.1, LINC02518, AL513123.1, RPS27AP11, LINC02541, FO393415.2, FO393415.1, MARCKS, MROCKI, LINC02880, HDAC2, HDAC2-AS2, NUDT19P3, HS3ST5, RPSAP43, RNA5SP213, DNAJA1P4, AL138830.2, AL138830.1.
- chr7:70,972–62,275,678, 1,079 genes, copy number 11–16 (broad region; genes not listed).
- chr7:63,113,635–65,554,744, 130 genes, copy number 12 (broad region; genes not listed).
- chr7:69,507,510–70,793,506, 3 genes, copy number 9 (within-gene range 2–9): Y_RNA, CT66, AUTS2.
- chr7:149,191,043–149,226,238, 2 genes, copy number 16: AC004890.1, ZNF282.
- chr8:46,028,804–50,796,692, 74 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr10:52,411,135–53,038,544, 7 genes, copy number 10–16: THAP12P3, LNCAROD, MBL2, Y_RNA, AC073174.1, LINC02672, SNRPEP8.
- chr17:9,764,186–10,198,606, 9 genes, copy number 9 (within-gene range 5–9): AC027045.2, DHRS7C, AC027045.1, GSG1L2, AC027045.3, GLP2R, NPM1P45, RCVRN, GAS7.
- chr17:28,755,978–29,294,148, 29 genes, copy number 10: FAM222B, RPL31P58, Y_RNA, AC024267.2, ERAL1, AC024267.1, MIR451A, MIR451B, MIR144, MIR4732, FLOT2, AC024267.3, AC024267.6, DHRS13, PHF12, AC024267.4, AC024267.5, PIPOX, SEZ6, AC024619.2, AC024619.1, AC024619.4, MYO18A, TIAF1, AC024619.3, AC005412.1, TWF1P1, CRYBA1, NUFIP2.
- chr17:30,378,927–30,895,869, 30 genes, copy number 17 (within-gene range 3–17): CPD, GOSR1, ALOX12P1, AC011840.3, AC011840.5, TBC1D29P, AC011840.4, AC011840.2, KRT17P3, AC011840.1, AC005562.1, SMURF2P1, AC005562.2, SH3GL1P2, LRRC37BP1, RN7SL316P, SUZ12P1, AC127024.7, AC127024.3, AC127024.2, AC127024.8, CRLF3, AC127024.4, AC127024.5, AC127024.6, AC127024.1, ATAD5, AC130324.2, RNU6-298P, AC130324.1.
- chr17:36,861,674–37,940,790, 31 genes, copy number 18–40: LHX1-DT, LHX1, AC243773.1, AATF, AC243773.2, AC244093.4, MIR2909, AC244093.3, AC244093.5, ACACA, AC244093.1, HMGB1P24, AC244093.2, C17orf78, AC243654.3, TADA2A, AC243654.1, AC243654.2, DUSP14, SYNRG, AC243585.2, DDX52, MIR378J, AC243571.2, AC243585.1, HNF1B, AC243571.1, YWHAEP7, RNU6-489P, TBC1D3K, 5S_rRNA.
- chr17:71,596,338–73,931,436, 40 genes, copy number 9–14 (within-gene range 8–14): AC118653.1, MYL6P5, AC007432.1, AC005144.1, ROCR, LINC01152, AC007461.1, SOX9-AS1, LINC02097, SOX9, LINC00511, LINC02003, AC007639.1, RPL32P33, AC080037.2, SLC39A11, RN7SKP180, AC080037.1, AC011120.1, ATG12P1, POLR3KP2, AC097641.1, SSTR2, COG1, AC097641.2, FAM104A, C17orf80, AC087301.1, CPSF4L, CDC42EP4, SDK2, AC124804.1, AC032019.1, AC032019.2, AC125421.1, LINC00469, LINC02092, AC125421.2, AC137735.1, AC137735.3.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
